EXCEPTIONAL_RESPONDERS case ER-ABVN — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b6379552-d318-451f-91d0-934bd6d18533

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1933; Vital status: Alive.

Diagnoses (2)
1. Gastrointestinal stromal tumor, malignant: ICD-O-3 morphology code: 8936/3; Tissue or organ of origin: Abdomen, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: recurrence; Age at diagnosis: 73.8 years (26,949 days); Year of diagnosis: 2007; AJCC pathologic stage: Stage X; Prior malignancy: yes; Days to last follow up: 2,997 days (8.2 years); Days to best overall response: 2,719 days (7.4 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Sunitinib Malate; Days to treatment start: 1,972 days (5.4 years); Days to treatment end: 2,875 days (7.9 years).
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Breast, NOS; Age at diagnosis: 72.3 years (26,425 days); AJCC pathologic stage: Stage III.

Follow-up (1 entry)
- Days to follow up: 2,997 days (8.2 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 1,935 days (5.3 years); Days progression-free: 2,997 days (8.2 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABVN-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Preservation method: FFPE.
  Slide ER-ABVN-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
